Somatic mutation profile of tumor specimen 0DTUIT from CCDI case PBCKHI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.7 years (5,366 days).
Specimen 0DTUIT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03130f9d-5458-42f6-b727-6c51d4ea5687.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTUI4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2f96288-2e87-405a-8b1e-90eb7230ca16

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EEF2K | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 127/340 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as rs775963419, COSV53787474; called by muse, mutect2, varscan2
- PTGS1 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 125/367 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV56290012; called by muse, mutect2, varscan2
- PRAMEF17 | c.140G>C p.R47T | Missense Mutation (SNP) | VAF 20/474 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- TBC1D22A | c.1373C>G p.A458G | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- NEB | c.8889+538A>G | Intron (SNP) | VAF 38/361 reads (11%) | called by muse, mutect2, varscan2
- TRIM27 | c.-23G>A | 5'UTR (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
